Somatic mutation profile of tumor specimen 0DFYQR from CCDI case PBBSTP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,378 days).
Specimen 0DFYQR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f0b69df-fbef-4488-b02c-ebd9d79d3348.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2f4a323-531b-452f-b0dd-741cf4f45898

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SBNO2 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated, low confidence (0.69); PolyPhen probably damaging (0.982); catalogued as rs751457572; called by muse, mutect2, varscan2
- CFAP54 | c.2889+2T>C p.X963_splice | Splice Site (SNP) | VAF 134/388 reads (35%) | called by muse, mutect2, varscan2
- LGR6 | c.982A>G p.T328A (on ENST00000367278 / NM_001017403.1; = p.T276A on NM_021636.3) | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.326); called by muse, mutect2, varscan2
